Somatic mutation profile of tumor specimen 0DT69E from CCDI case PBCIZB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.8 years (5,760 days).
Specimen 0DT69E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0c83416-f02f-4fbb-bcd0-54c6c73475ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT699 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/051f2209-9dab-4690-81af-7c0fa3e662f3

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD2 | c.1637C>T p.T546I | Missense Mutation (SNP) | VAF 37/897 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2
- DMRTA2 | c.1040T>A p.I347N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- GBA2 | c.1668C>T p.L556= | Silent (SNP) | VAF 72/348 reads (21%) | called by muse, mutect2, varscan2
- CHD6 | c.975-76G>A | Intron (SNP) | VAF 65/124 reads (52%) | catalogued as rs182665373; called by muse, mutect2, varscan2
- EXD1 | c.691-88A>C | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
